Somatic mutation profile of tumor specimen MMRF_2730_1_BM_CD138pos (aliquot MMRF_2730_1_BM_CD138pos_T1_KHS5U_L14872) from MMRF case MMRF_2730, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.7 years (21,060 days).
Specimen MMRF_2730_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0897b308-efb8-423d-8a0e-fb379ee27c87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2730_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2730_1_PB_WBC_C2_KHS5U_L14873; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53d31368-0db9-4ac3-9f23-93352a39f92b

The open-access MAF lists 88 somatic variants for this specimen: 23 protein-altering or splice-affecting, 14 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 23, Intron 17, Missense Mutation 17, Silent 14, 3'Flank 4, 5'UTR 3, RNA 3, Frame Shift Del 2, Splice Region 2, 5'Flank 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 102/236 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLNB | c.3637G>A p.V1213M | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760397310; called by muse, mutect2, varscan2
- IGHV3-30 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as rs1280778312; called by mutect2, varscan2
- IRF7 | c.808G>A p.E270K (on ENST00000397566; = p.E257K on NM_001572.5) | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0.182); catalogued as rs1160609325, COSV52750603, COSV52757118, COSV99199614; called by muse, mutect2, varscan2
- PCSK6 | c.1414+5G>A | Splice Region (SNP) | VAF 17/105 reads (16%) | catalogued as rs776148817; called by muse, mutect2, varscan2
- RIMBP2 | c.2162C>T p.S721L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756866703, COSV55483310; called by muse, mutect2, varscan2
- SERINC3 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.206); catalogued as rs1407900622, COSV99668103; called by muse, mutect2, varscan2
- SHD | c.461del p.E154Gfs*92 | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | catalogued as COSV73378697; called by mutect2, pindel, varscan2
- AP002495.1 | c.28C>T p.H10Y | Missense Mutation (SNP) | VAF 75/437 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNNM2 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- COL27A1 | c.2127A>T p.G709= | Splice Region (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- CPD | c.3952A>C p.I1318L | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.952); called by muse, mutect2
- DCDC2 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- HEXA | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- HOXD4 | c.639T>A p.H213Q | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ISG20 | c.167_217del p.V56_V72del | In Frame Del (DEL) | VAF 44/286 reads (15%) | called by mutect2, pindel
- LRBA | c.1033del p.L345Wfs*17 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | called by mutect2, pindel, varscan2
- MASP2 | c.500G>C p.C167S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPP3 | c.1458+1G>A p.X486_splice | Splice Site (SNP) | VAF 49/164 reads (30%) | called by muse, mutect2, varscan2
- NCAPH | c.133A>C p.N45H | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.694); called by muse, mutect2
- SHB | c.969C>A p.S323R | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TFIP11 | c.2444T>C p.V815A | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- VPS13B | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ANKRD11 | c.4155C>T p.S1385= | Silent (SNP) | VAF 45/147 reads (31%) | called by muse, mutect2, varscan2
- CEP152 | c.4440C>T p.D1480= (on ENST00000380950 / NM_001194998.2; = p.D1424= on NM_014985.4) | Silent (SNP) | VAF 92/397 reads (23%) | catalogued as COSV57864383; called by muse, mutect2, varscan2
- GPLD1 | c.1839C>T p.H613= | Silent (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- HS3ST6 | c.684C>T p.Y228= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as rs372109673; called by muse, mutect2, varscan2
- IL20 | c.484T>C p.L162= | Silent (SNP) | VAF 91/197 reads (46%) | catalogued as rs776742036; called by muse, mutect2, varscan2
- NPAP1 | c.144C>T p.R48= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as rs1326901821, COSV61506287; called by muse, mutect2, varscan2
- OBSCN | c.658C>T p.L220= | Silent (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- PALM3 | c.1104G>A p.G368= (on ENST00000340790; = p.G383= on NM_001145028.2) | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as rs1003920972; called by muse, mutect2, varscan2
- PHETA1 | c.672C>T p.F224= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as rs1032315792, COSV100825300; called by muse, mutect2, varscan2
- PLA2G6 | c.534G>A p.Q178= | Silent (SNP) | VAF 55/149 reads (37%) | catalogued as rs1166238427; called by muse, mutect2, varscan2
- PLEKHG4B | c.2265G>A p.L755= (on ENST00000283426; = p.L1111= on NM_052909.5) | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs1337543069; called by muse, mutect2, varscan2
- ROBO2 | c.1533A>C p.T511= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2
- SCIN | c.1732T>C p.L578= (on ENST00000297029 / NM_001112706.3; = p.L331= on NM_033128.3) | Silent (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- SH3RF3 | c.492G>T p.P164= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1192615202; called by muse, mutect2, varscan2
- ABCC9 | c.406+2281G>T | Intron (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- AC006305.1 | n.1077A>G | RNA (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- AC092070.2 | n.96G>A | RNA (SNP) | VAF 129/295 reads (44%) | called by muse, mutect2, varscan2
- ACER2 | c.*765dup | 3'UTR (INS) | VAF 24/145 reads (17%) | called by mutect2, pindel, varscan2
- BCAT1 | c.*5630A>G | 3'UTR (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021517 G>C | 5'Flank (SNP) | VAF 59/195 reads (30%) | catalogued as COSV55846497, COSV55849856; called by muse, mutect2, varscan2
- BDKRB2 | c.75-706T>C | Intron (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- BEND7 | c.1081+3658A>C | Intron (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- C7orf25 | c.-21-61T>C | Intron (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- CCSER2 | c.*1437C>T | 3'UTR (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- COL27A1 | c.2368-1412T>A | Intron (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- DBNL | c.-12G>A | 5'UTR (SNP) | VAF 14/78 reads (18%) | catalogued as rs1437033564; called by muse, mutect2, varscan2
- DCAF12 | c.79-325A>T | Intron (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.*1219C>T | 3'UTR (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13892838 C>T | 3'Flank (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- FBN1 | c.*2329T>C | 3'UTR (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- FSTL1 | c.*2923T>C | 3'UTR (SNP) | VAF 33/144 reads (23%) | catalogued as rs1195065162; called by muse, mutect2, varscan2
- FSTL4 | c.*1621G>A | 3'UTR (SNP) | VAF 40/99 reads (40%) | catalogued as rs1485758919; called by muse, mutect2, varscan2
- G3BP2 | c.*1449C>G | 3'UTR (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- GTF3C4 | c.*530G>T | 3'UTR (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- IKZF1 | c.*377T>A | 3'UTR (SNP) | VAF 49/188 reads (26%) | called by muse, varscan2
- KCNMB3P1 | n.2708A>G | RNA (SNP) | VAF 30/102 reads (29%) | catalogued as rs1052028139; called by muse, mutect2, varscan2
- KCTD3 | c.1563-23C>A | Intron (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- KLF4 | c.*100G>A | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- KLK12 | c.-19-28G>A | Intron (SNP) | VAF 31/135 reads (23%) | called by muse, mutect2, varscan2
- LIN28B | c.*3464A>G | 3'UTR (SNP) | VAF 78/246 reads (32%) | called by muse, mutect2, varscan2
- MASP2 | c.544+315G>T | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs1005715421; called by muse, mutect2, varscan2
- MASP2 | c.544+208G>C | Intron (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- MASP2 | c.544+104G>C | Intron (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- MASP2 | c.413-31G>A | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- NKX3-1 | c.*2349T>C | 3'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- NKX3-1 | c.*2348A>G | 3'UTR (SNP) | VAF 16/34 reads (47%) | catalogued as rs1053112752; called by muse, mutect2, varscan2
- PPIC | c.*280del | 3'UTR (DEL) | VAF 11/71 reads (15%) | catalogued as rs1277469134; called by mutect2, pindel, varscan2
- PTPN20 | chr10:47000865 T>A | 3'Flank (SNP) | VAF 96/319 reads (30%) | catalogued as rs1287188343; called by muse, mutect2, varscan2
- PXDN | c.2104+94C>A | Intron (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- RBM5 | c.483+623C>T | Intron (SNP) | VAF 11/64 reads (17%) | catalogued as rs1039436999; called by muse, mutect2, varscan2
- SH3BP4 | c.*1798C>A | 3'UTR (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- SHANK1 | c.*58G>A | 3'UTR (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- SLITRK6 | c.*1164C>A | 3'UTR (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- SMIM21 | c.*15C>A | 3'UTR (SNP) | VAF 22/249 reads (9%) | catalogued as COSV101232324; called by muse, mutect2
- SMU1 | c.*2764C>T | 3'UTR (SNP) | VAF 24/83 reads (29%) | catalogued as rs1274874483; called by muse, mutect2, varscan2
- SPINT1 | c.*1183C>T | 3'UTR (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- STXBP6 | c.*1767C>T | 3'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133554310 G>T | 3'Flank (SNP) | VAF 61/220 reads (28%) | called by muse, mutect2, varscan2
- TNS1 | c.-43G>T | 5'UTR (SNP) | VAF 6/31 reads (19%) | catalogued as rs948784011; called by muse, mutect2, varscan2
- TP53I13 | c.142-68T>A | Intron (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- TRAF3IP1 | c.-93C>T | 5'UTR (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- TSPAN13 | c.*29A>T | 3'UTR (SNP) | VAF 119/330 reads (36%) | called by muse, varscan2
- TSPEAR | c.1566+2028G>A | Intron (SNP) | VAF 45/206 reads (22%) | catalogued as rs782180440; called by muse, mutect2, varscan2
- TSPEAR | c.543-34C>T | Intron (SNP) | VAF 40/166 reads (24%) | called by muse, mutect2, varscan2
- ZBED1 | chrX:2486659 C>G | 3'Flank (SNP) | VAF 9/85 reads (11%) | called by mutect2, varscan2
